CCDI case PBBPXA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Nasopharynx.
https://portal.gdc.cancer.gov/cases/695b6a08-19a0-4c16-8524-d86820d2c282

Demographics
Sex at birth: male; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Carcinoma, metastatic, NOS: ICD-O-3 morphology code: 8010/6; Tissue or organ of origin: Lateral wall of nasopharynx; Age at diagnosis: 16.5 years (6,016 days).

Biospecimens (3 samples)
- Sample 0DEHN4: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DEHQ5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DEHQ6: Tissue type: Tumor; Specimen type: Solid Tissue.
